Somatic mutation profile of tumor specimen TCGA-KO-8416-01A (aliquot TCGA-KO-8416-01A-11D-2310-10) from TCGA case TCGA-KO-8416, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 41.8 years (15,261 days).
Specimen TCGA-KO-8416-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cad74822-2f58-4a9a-bb19-275157e2e949.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8416-11A (Solid Tissue Normal), aliquot TCGA-KO-8416-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4bceb99-5c1b-4df8-8712-7f8dac04dc8c

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, varscan2
- MAGEL2 | c.1993C>A p.P665T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1299091859, COSV100046091; called by muse, mutect2
- SLC6A14 | c.346+1del | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | catalogued as COSV100903099; called by mutect2, pindel, varscan2
- ZNF528 | c.1580G>T p.G527V | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64620729; called by muse, mutect2
- ARHGAP32 | c.4835A>G p.Y1612C (on ENST00000310343 / NM_001378025.1; = p.Y1263C on NM_014715.4) | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- CCDC185 | c.1429A>G p.K477E | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2
- OR1S2 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2
- YTHDC1 | c.1176A>T p.R392S (on ENST00000344157 / NM_001031732.4; = p.R374S on NM_133370.4) | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AL121899.2 | c.1122T>C p.A374= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs1380483526; called by muse, mutect2, varscan2
- CLECL1 | c.255C>T p.Y85= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs767578087, COSV59931162; called by muse, mutect2, varscan2
- UCN3 | c.279C>T p.T93= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100991723; called by muse, mutect2
